Somatic mutation profile of tumor specimen TCGA-44-6148-01A (aliquot TCGA-44-6148-01A-11D-1753-08) from TCGA case TCGA-44-6148, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.6 years (22,138 days).
Specimen TCGA-44-6148-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa07bdd7-6bfc-404e-9632-42837c8aff73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6148-10A (Blood Derived Normal), aliquot TCGA-44-6148-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3444cf6c-2deb-4d67-a29e-0fd40fd3d634

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DAP3 | c.1144T>C p.F382L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as rs1431035105, COSV58019539; called by muse, mutect2
- HADHA | c.1799C>G p.A600G | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as COSV66108361; called by muse, mutect2, varscan2
- PARP3 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs374239491; called by muse, mutect2, varscan2
- ZFPM2 | c.1469C>A p.P490H | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65875298; called by muse, mutect2, varscan2
- CWF19L2 | c.1428_1431del p.F476Lfs*12 | Frame Shift Del (DEL) | VAF 24/167 reads (14%) | called by mutect2, pindel, varscan2
- AMER3 | c.1950C>T p.V650= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1483336643, COSV58467970; called by muse, mutect2, varscan2
